Surgical pathology report (de-identified scan), TCGA case TCGA-EJ-7782, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site University of Pittsburgh, specimen TCGA-EJ-7782-01A (Primary Tumor).

PATIENT HISTORY:

CHIEF COMPLAINT/PRE-OP/POST-OP DIAGNOSIS: Prostate cancer.
PROCEDURE: Radical retropubic prostatectomy; flexible cystoscopy.
SPECIFIC CLINICAL QUESTION: Not stated.
OUTSIDE TISSUE DIAGNOSIS: Not stated.
PRIOR MALIGNANCY: Not stated.
CHEMORADIATION: Not stated.
ORGAN TRANSPLANT: Not stated.
IMMUNOSUPPRESSION: Not stated.
OTHER DISEASES: Not stated.

FINAL DIAGNOSIS:**PART 1: LYMPH NODES, RIGHT PELVIC, EXCISION –**

NO EVIDENCE OF NEOPLASIA IN EIGHT (8) LYMPH NODES EXAMINED.

PART 2: LYMPH NODES, LEFT PELVIC, EXCISION –

NO EVIDENCE OF NEOPLASIA IN NINE (9) LYMPH NODES EXAMINED.

PART 3: PROSTATE AND BILATERAL SEMINAL VESICLES, RADICAL PROSTATECTOMY –

- A. INVASIVE POORLY DIFFERENTIATED ADENOCARCINOMA, GLEASON SCORE 4 + 4 = 8.
- B. THE CARCINOMA INVOLVES BOTH THE RIGHT AND LEFT LOBES AND HAS A GREATEST NODULAR DIAMETER OF 1.2 CM.
- C. THE CARCINOMA INVOLVES 5% OF THE EXAMINED PROSTATE VOLUME.
- D. THE CARCINOMA IS ORGAN CONFINED AND SHOWS NO EVIDENCE OF EXTRACAPSULAR EXTENSION.
- E. BILATERAL SEMINAL VESICLES ARE FREE OF CARCINOMA.
- F. ALL EXAMINED SURGICAL RESECTION MARGINS ARE FREE OF CARCINOMA.
- G. PERINEURAL INVASION IS IDENTIFIED.
- H. NO ANGIOLYMPHATIC INVASION IS IDENTIFIED.
- I. HIGH-GRADE PROSTATIC INTRAEPITHELIAL NEOPLASIA IS IDENTIFIED.
- J. PATHOLOGIC TNM STAGE: pT2c N0 MX.
- K. TNM HISTOLOGIC GRADE = G4.
- L. BENIGN PROSTATIC HYPERTROPHY AND CHRONIC MODERATELY ACTIVE PROSTATITIS ARE NOTED.

PART 4: LYMPH NODE, LEFT PERIVESICAL, EXCISION –

NO EVIDENCE OF NEOPLASIA IN TWO (2) LYMPH NODES EXAMINED.

CASE SYNOPSIS:**SYNOPTIC DATA - PRIMARY PROSTATE TUMORS**

INVASIVE CA IDENTIFIED?:	Yes
TUMOR HISTOLOGY:	Adenocarcinoma NOS
PRIMARY GLEASON GRADE:	4
SECONDARY GLEASON GRADE:	4
GLEASON SUM SCORE:	8
GLEASON 4/5 PERCENTAGE:	100%
WEIGHT OF PROSTATE:	91.54gm
TUMOR SIZE:	Maximum dimension: 1.2 cm
LOBE LATERALITY:	Right and Left Lobes
PERCENT OF SPECIMEN INVOLVED BY TUMOR:	5 - 25%
MULTIFOCAL DISEASE:	Yes
HIGH GRADE PIN:	Yes - NOS
EXTRAPROSTATIC EXTENSION:	No
PERINEURAL INVASION:	Yes
ANGIOLYMPHATIC INVASION:	No
SEMINAL VESICLE INVASION:	No
SURGICAL MARGIN INVOLVEMENT:	All surgical margins free of tumor
LYMPH NODES EXAMINED:	19
LYMPH NODES POSITIVE:	0
T STAGE, PATHOLOGIC:	pT2c
N STAGE, PATHOLOGIC:	pN0
M STAGE, PATHOLOGIC:	pMX
HISTOLOGIC GRADE:	G3-4, Poorly differentiated/undifferentiated

Source: NCI Genomic Data Commons file adbd2aa5-b821-44f8-96fc-9336e20f0696 (TCGA-EJ-7782.D8500E84-1AA4-4A3B-874C-563D520DEC03.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).